Somatic mutation profile of tumor specimen MBCProject_2290_T2_WES (aliquot MBCProject_2290_T2_WES_1) from CMI case MBCProject_2290, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.3 years (15,833 days).
Specimen MBCProject_2290_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb31b97b-99a5-4b4b-add8-f73a752996b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2290_SALIVA (Saliva), aliquot MBCProject_2290_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/442db794-3a92-4dd6-a04b-6bc926f7ff7a

The open-access MAF lists 138 somatic variants for this specimen: 91 protein-altering or splice-affecting, 31 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 31, Intron 10, In Frame Del 5, 3'UTR 4, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, Nonstop Mutation 1, RNA 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>G p.Y163D | Missense Mutation (SNP) | VAF 106/192 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as COSV51547216; called by muse, mutect2, varscan2
- ASTN1 | c.472-1G>C p.X158_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99920686, COSV99923452; called by muse, mutect2
- ATP13A4 | c.719C>G p.T240R | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770995802; called by muse, mutect2, varscan2
- ATP2A3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 127/260 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs773733827; called by muse, mutect2, varscan2
- ATP8B4 | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV99468398; called by muse, mutect2
- BRCA2 | c.9800A>G p.K3267R | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1323152399; called by muse, mutect2
- C4orf17 | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV58512251; called by muse, mutect2, varscan2
- CCBE1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs368065685; called by muse, mutect2, varscan2
- CFAP61 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs201899206, COSV55647489; called by muse, mutect2
- CFAP65 | c.3057C>A p.D1019E | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV58566121; called by muse, mutect2, varscan2
- CPEB4 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | catalogued as rs1412208413, COSV99436987; called by muse, varscan2
- CUBN | c.2795G>A p.C932Y | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs572470830; called by muse, varscan2
- DYNC2H1 | c.2857A>G p.M953V | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749396774; called by muse, mutect2, varscan2
- ERBB4 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV53532942; called by muse, varscan2
- HCN1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100301324, COSV100301894; called by muse, mutect2, varscan2
- HPRT1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 78/297 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as CD137579, CM125264; called by muse, mutect2, varscan2
- JARID2 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs571642301; called by muse, mutect2, varscan2
- LAMB4 | c.3664G>A p.G1222R | Missense Mutation (SNP) | VAF 34/290 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV52725946; called by muse, mutect2, varscan2
- NLRP5 | c.2596T>A p.C866S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs755525227; called by muse, mutect2, varscan2
- NRP1 | c.1542G>T p.K514N | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1470644534; called by muse, mutect2, varscan2
- OR10H2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV59946318, COSV59947124; called by muse, mutect2, varscan2
- PCNX2 | c.5300G>A p.R1767K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867309597, COSV50787683; called by muse, mutect2
- SCO2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 225/475 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as rs373674489; called by muse, mutect2, varscan2
- SOX5 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs759171095, COSV100507662; called by muse, mutect2, varscan2
- SSB | c.925G>T p.E309* | Nonsense Mutation (SNP) | VAF 44/223 reads (20%) | catalogued as COSV99641741; called by muse, mutect2, varscan2
- TBC1D32 | c.2666G>C p.R889T | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978204879, COSV99250000; called by muse, mutect2, varscan2
- UPF1 | c.3197C>T p.T1066M (on ENST00000599848 / NM_001297549.2; = p.T1055M on NM_002911.4) | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs907984314, COSV53193721; called by muse, mutect2, varscan2
- ZNF112 | c.2147C>G p.S716C (on ENST00000337401 / NM_001083335.2; = p.S710C on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV61620610; called by muse, mutect2
- AASDH | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- AGAP6 | c.1381A>G p.T461A (on ENST00000374056 / NM_001365867.1; = p.T484A on NM_001077665.2) | Missense Mutation (SNP) | VAF 34/593 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.124); called by muse, mutect2
- ALX1 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ASTN2 | c.1949G>A p.G650E (on ENST00000313400 / NM_001365069.1; = p.G599E on NM_014010.5) | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATF7IP | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2
- BHLHE22 | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, varscan2
- C2CD4A | c.51C>A p.S17R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- C7orf31 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.046); called by muse, mutect2
- CAPN12 | c.2017_2022del p.L673_R674del | In Frame Del (DEL) | VAF 34/356 reads (10%) | called by mutect2, pindel
- CD40 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CIT | c.3048G>T p.K1016N | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CLASP2 | c.1007A>C p.D336A | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CLDN1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- DNAH10 | c.990G>C p.K330N (on ENST00000409039; = p.K269N on NM_207437.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DNAH5 | c.12991G>A p.D4331N | Missense Mutation (SNP) | VAF 25/688 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- EVPL | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- FAM13C | c.1424A>C p.H475P | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- FBXW10 | c.469_474del p.R157_V158del | In Frame Del (DEL) | VAF 30/204 reads (15%) | called by mutect2, pindel, varscan2
- FCER2 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- FLNA | c.4861_4887del p.K1621_F1629del | In Frame Del (DEL) | VAF 24/158 reads (15%) | called by mutect2, pindel
- GCN1 | c.4133T>C p.I1378T | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2
- IQGAP3 | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1671 | c.1809T>G p.D603E | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- LAMA3 | c.7590T>G p.N2530K (on ENST00000313654 / NM_198129.4; = p.N921K on NM_000227.6) | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); called by muse, mutect2
- LCAT | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.069); called by muse, mutect2
- LRRK2 | c.6203C>A p.T2068K | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYST | c.4625T>C p.L1542P | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAEA | c.1162_*12del | Nonstop Mutation (DEL) | VAF 41/206 reads (20%) | called by mutect2, pindel
- MAMDC4 | c.2701+2T>C p.X901_splice (on ENST00000445819; = p.X822_splice on NM_206920.3) | Splice Site (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- MSH6 | c.532_543del p.R178_E181del | In Frame Del (DEL) | VAF 64/325 reads (20%) | called by mutect2, pindel, varscan2
- MSRB1 | c.69T>G p.C23W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.34198G>A p.V11400I | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- MYO6 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); called by muse, mutect2
- NLRX1 | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OR14C36 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAMR1 | c.1534G>T p.V512F (on ENST00000619888 / NM_001001991.3; = p.V529F on NM_015430.4) | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PCSK5 | c.2744_2779del p.G915_F926del | In Frame Del (DEL) | VAF 24/200 reads (12%) | called by mutect2, pindel
- PTPN23 | c.3796C>G p.L1266V | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBL2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- REV3L | c.8492del p.T2831Kfs*25 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, varscan2
- RPN2 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 61/433 reads (14%) | called by muse, mutect2, varscan2
- SCN11A | c.1688G>T p.W563L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCP2 | c.729del p.K244Sfs*16 | Frame Shift Del (DEL) | VAF 67/389 reads (17%) | called by mutect2, pindel, varscan2
- SDR42E2 | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- SERPINH1 | c.550A>C p.K184Q | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC12A6 | c.1730T>A p.F577Y (on ENST00000354181 / NM_001365088.1; = p.F526Y on NM_005135.2) | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC19A2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC6A17 | c.1344_1351del p.M449Lfs*74 | Frame Shift Del (DEL) | VAF 17/189 reads (9%) | called by mutect2, pindel
- SRXN1 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by mutect2, varscan2
- STXBP5L | c.1532A>G p.E511G | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TAS1R3 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TCP10L2 | c.869A>C p.Q290P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.14); called by mutect2, varscan2
- TENM1 | c.2870A>T p.Q957L | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- THBS2 | c.1852C>A p.H618N | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TMC6 | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRIM2 | c.274C>G p.R92G (on ENST00000437508; = p.R119G on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2
- TSPEAR | c.1133T>C p.F378S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TUBB | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- VAV1 | c.544_558+7del p.X182_splice | Splice Site (DEL) | VAF 26/174 reads (15%) | called by mutect2, pindel
- YES1 | c.65C>A p.P22Q | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF195 | c.723G>C p.E241D (on ENST00000399602 / NM_001130520.3; = p.E169D on NM_007152.5) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZXDA | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 60/494 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADAMTS12 | c.4239C>A p.P1413= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as rs952833728, COSV61261646, COSV61268077; called by muse, mutect2, varscan2
- ANKUB1 | c.1302T>A p.A434= | Silent (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- BHLHE22 | c.549C>G p.G183= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, varscan2
- C18orf25 | c.588G>A p.K196= | Silent (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- CERK | c.696G>C p.R232= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV53450003; called by muse, mutect2
- CIDEC | c.198C>A p.L66= | Silent (SNP) | VAF 39/213 reads (18%) | called by muse, mutect2, varscan2
- DNAH11 | c.12264C>T p.H4088= | Silent (SNP) | VAF 86/288 reads (30%) | catalogued as rs368428210; called by muse, varscan2
- DZANK1 | c.163C>T p.L55= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV52747721; called by muse, mutect2
- HSPA6 | c.657T>C p.F219= | Silent (SNP) | VAF 162/338 reads (48%) | catalogued as rs759922022; called by muse, mutect2, varscan2
- ICA1L | c.1338C>T p.P446= | Silent (SNP) | VAF 32/121 reads (26%) | called by muse, mutect2, varscan2
- ITGA11 | c.2568A>T p.L856= | Silent (SNP) | VAF 41/184 reads (22%) | called by muse, mutect2, varscan2
- KBTBD2 | c.1644A>G p.K548= | Silent (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- MIA3 | c.5172C>T p.P1724= | Silent (SNP) | VAF 62/165 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.4620G>T p.L1540= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- MYH9 | c.4921C>A p.R1641= | Silent (SNP) | VAF 11/202 reads (5%) | called by muse, mutect2
- OIT3 | c.144T>C p.P48= | Silent (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- PKP3 | c.1770G>A p.A590= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs768160226; called by muse, mutect2
- POMT1 | c.303G>A p.V101= | Silent (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- RBMXL3 | c.936C>T p.G312= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs782770623, COSV100407533; called by muse, mutect2, varscan2
- RSPH1 | c.657G>T p.L219= | Silent (SNP) | VAF 22/336 reads (7%) | catalogued as rs1486800299; called by muse, mutect2
- SCUBE2 | c.1881G>A p.R627= | Silent (SNP) | VAF 59/368 reads (16%) | catalogued as rs900621426, COSV58543750; called by muse, mutect2, varscan2
- SH2B2 | c.414G>A p.E138= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV60827265; called by muse, mutect2, varscan2
- SLITRK5 | c.1401C>T p.N467= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs752830518, COSV61521526; called by muse, mutect2, varscan2
- SMCHD1 | c.1578G>A p.L526= | Silent (SNP) | VAF 35/189 reads (19%) | called by muse, mutect2, varscan2
- TMEM196 | c.513G>A p.P171= | Silent (SNP) | VAF 68/264 reads (26%) | catalogued as rs770025109; called by muse, mutect2, varscan2
- UQCRFS1 | c.300G>A p.T100= | Silent (SNP) | VAF 28/528 reads (5%) | catalogued as rs1326497311, COSV59185143; called by muse, mutect2
- VPS13C | c.11085T>C p.G3695= (on ENST00000644861 / NM_020821.3; = p.G3652= on NM_017684.5) | Silent (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- ZBTB39 | c.1875G>A p.R625= | Silent (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- ZNF14 | c.903T>C p.H301= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1365727474; called by muse, mutect2
- ZNF317 | c.735C>T p.T245= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs751297958; called by muse, mutect2, varscan2
- ZNF469 | c.10899C>T p.P3633= (on ENST00000437464; = p.P3661= on NM_001367624.2) | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- AC027559.1 | n.321G>A | RNA (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- AC114490.3 | c.*364G>A | 3'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- CAPS | chr19:5914139 A>C | 5'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- CLEC10A | c.67+12_67+29del | Intron (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel
- CRLS1 | c.574+15T>C | Intron (SNP) | VAF 71/280 reads (25%) | called by muse, mutect2, varscan2
- DUOX2 | c.3184+20G>T | Intron (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
- ECHDC1 | c.381+488A>C | Intron (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- ERAP1 | c.*216C>G | 3'UTR (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- FGFR2 | c.2302-31G>A | Intron (SNP) | VAF 27/332 reads (8%) | called by muse, mutect2
- IER3 | c.211-34G>C | Intron (SNP) | VAF 22/245 reads (9%) | catalogued as rs533879458; called by muse, mutect2
- LAIR1 | c.35-156C>T | Intron (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2, varscan2
- MUC19 | c.162+9T>A | Intron (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- NDUFB9 | c.*45A>T | 3'UTR (SNP) | VAF 81/266 reads (30%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4289C>G | Intron (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- SLC35A2 | c.92-281G>A | Intron (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- ZNF626 | c.*70C>G | 3'UTR (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
